TCGA case TCGA-AQ-A04J — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9938ce5c-e74e-446e-a932-f096f85cc3b1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 45.5 years (16,615 days); Year of diagnosis: 2009; Method of diagnosis: Core Biopsy; AJCC pathologic T: T2; AJCC pathologic N: N0 (i+); AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 20; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 61 days; Days to treatment end: 104 days; Number of cycles: 4; Treatment dose: 2,400 mg/m2; Prescribed dose: 600; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 61 days; Days to treatment end: 104 days; Number of cycles: 4; Treatment dose: 240 mg/m2; Prescribed dose: 60; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 118 days; Days to treatment end: 160 days; Number of cycles: 4; Treatment dose: 700 mg/m2; Prescribed dose: 175; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 160 days; Disease response: Tumor Free.
- Days to follow up: 500 days (1.4 years); Disease response: Tumor Free.
- Days to follow up: 819 days (2.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 0; Test value range: <10%.
- ESR1 (IHC): Negative; Staining intensity value: 0; Test value range: <10%.
- PGR (IHC): Negative; Staining intensity value: 0; Test value range: <10%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AQ-A04J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 160 mg.
  Slide TCGA-AQ-A04J-01A-01-BS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AQ-A04J-01A-02-MS2: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 65; Percent normal cells: 8; Percent necrosis: 15; Percent stromal cells: 27; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-AQ-A04J-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AQ-A04J-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: No; Er IHC score: 0; Her2 IHC score: 0; Method initial path diagnosis: Core needle biopsy; Her2 IHC percent positive: <10%; Prospective collection: No; Retrospective collection: Yes; Er status IHC Percent Positive: <10%; Pr status IHC percent positive: <10%; Pr positivity IHC intensity score: 0.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Outer Quadrant.
- Follow-up form 2: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Adriamycin.
- Drug treatment 3: Regimen number: 1; Pharmaceutical therapy drug name: Taxol.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 819 days; disease-specific survival: no event (censored), 819 days; disease-free interval: no event (censored), 819 days; progression-free interval: no event (censored), 819 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AQ-A04J-01A-02D-A036-01): tumor purity 0.45, ploidy 1.84, whole-genome doublings 0.
